Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-A61K, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-A61K-01A (Primary Tumor).

[page 1 of 8]
AGE/SEX: /F
REG DR:

Received:
Copies to:

Collected:

SPECIMEN ID:

A. LYMPH NODE - RIGHT NECK LEVEL 3,4, B. LYMPH NODE - RIGHT NECK LEVEL 1,
C. LYMPH NODE - RIGHT NECK LEVEL 2, D. LYMPH NODE - ADD'S RT LEVEL 4 TISSUE,
E. TONGUE - RT GLOSSECTOMY STITCH ANTERIOR FS, F. TONGUE - DORSAL TONGUE FS,
G. NERVE - PROXIMAL MARGIN RIGHT LINGUAL NERVE FS, H. TONGUE - RIGHT BASE OF TONGUE FS,
I. TONSIL - RT ANTERIOR TONSILLAR PILLAR FS, J. MOUTH - RETRO-MOLAR TRIGONE FS,
K. MOUTH - RT FLOOR OF MOUTH FS, L. TONGUE - VENTRAL TONGUE FS,
M. TONGUE - DEEP MARGIN BASE OF TONGUE FS, N. TONGUE - DEEP MARGIN ANTERIOR FS,
O. TONGUE - DEEP MARGIN-DEEP TONGUE FS, P. LYMPH NODE - LEVEL 5 LYMPH NODE FS,
Q. MOUTH - DISTAL RIGHT HYPOGLOSSAL FS, R. MOUTH - SUBMENTAL TRIANGLE

***** FINAL DIAGNOSIS *****

A. RIGHT NECK LEVEL 3,4:

METASTATIC CARCINOMA to two of nineteen lymph nodes (2/23).

Largest focus of carcinoma is 3.0 mm.

Extranodal extension is absent.

B. RIGHT NECK LEVEL 1:

METASTATIC CARCINOMA to one of five lymph nodes (1/5).

Largest focus of carcinoma is 0.9 cm.

Extranodal extensive is present.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

ICD O-3
Carcinoma, squamous cell
keratinizing NOS 8071/3
Site Tongue NOS C02.9
JW 5/14/13

[page 2 of 8]
*** FINAL DIAGNOSIS *** (Continued)

C. RIGHT NECK LEVEL 2:

METASTATIC CARCINOMA to one of thirteen lymph nodes (1/13).

Largest focus of carcinoma is 1.2 cm.

Extranodal extension is present.

D. ADDITIONAL RIGHT LEVEL 4 TISSUE:

One lymph node, negative for carcinoma (0/1).

E. RIGHT GLOSSECTOMY:

INVASIVE KERATINIZING SQUAMOUS CELL CARCINOMA, ulcerating, 4.1 cm in greatest dimension.

Surgical resection margins are negative.

Closest proximally is 5 mm from anterior resection margin.

Perineural invasion is present.

No definitive lymphovascular invasion is identified.

AJCC Classification (7th edition): pT3 N2b MX

See Tumor Summary.

F. DORSAL TONGUE:

Squamous mucosa and skeletal muscle, negative for carcinoma.

G. PROXIMAL MARGIN RIGHT LINGUAL NERVE:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 3 of 8]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Nerve, negative for carcinoma.

H. RIGHT BASE OF TONGUE:

Squamous mucosa, negative for carcinoma.

I. RIGHT ANTERIOR TONSILLAR PILLAR:

Squamous mucosa, negative for carcinoma.

J. RETRO-MOLAR TRIGONE:

Squamous mucosa, negative for carcinoma.

K. RIGHT FLOOR OF MOUTH:

Squamous mucosa, negative for carcinoma.

L. VENTRAL TONGUE:

Skeletal muscle and connective tissue, negative for carcinoma.

M. DEEP MARGIN BASE OF TONGUE:

Skeletal muscle and connective tissue, negative for carcinoma.

N. DEEP MARGIN ANTERIOR:

Fibroadipose tissue, negative for carcinoma.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail. [REDACTED]

[page 4 of 8]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

O. DEEP MARGIN DEEP TONGUE:

Fibroadiopose tissue, negative for carcinoma.

P. LEVEL 5 LYMPH NODE:

One lymph node, negative for carcinoma (0/1).

Q. DISTAL RIGHT HYPOGLOSSAL:

Nerve, negative for carcinoma.

R. SUBMENTAL TRIANGLE:

Five lymph nodes, negative for carcinoma (0/5).

Surgical Pathology Cancer Case Summary:

LIP AND ORAL CAVITY: Incisional Biopsy, Excisional Biopsy, Resection

Specimen:

Dorsal surface of tongue, NOS

Anterior two-thirds of tongue, NOS per clinical notes

Received: In formalin

Procedure: Resection

Glossectomy (specify): Hemiglossectomy

Specimen Integrity: Intact

Specimen Size:

Greatest dimensions: 6.1 x 4.1 x 3.6 cm

Specimen Laterality: Right

Tumor Site: Anterior two-thirds of tongue, NOS

Tumor Size: Greatest dimension: 4.1 cm

Additional dimensions: 3.1 x 0.2 cm

Tumor Description: Ulcerated

Histologic Type: Squamous cell carcinoma, conventional

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 5 of 8]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Histologic Grade: G2: Moderately differentiated

Margins: Uninvolved by invasive carcinoma:

Distance from closest margin: 0.5 cm

Specify margin(s), per orientation, if possible: Anterior

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Present

Lymph Nodes, Extranodal Extension: Present

Pathologic Staging:

Primary Tumor: pT3

Regional Lymph Nodes: pN2b

Number of Lymph Nodes Examined: 44

Number of Lymph Nodes Involved: 4

Distant Metastasis: Not applicable

CLINICAL HISTORY-

PRE-OP DX: NONE PROVIDED

PROCEDURE: NONE PROVIDED

RELEVANT CLINICAL HX: NONE PROVIDED

GROSS DESCRIPTION:

- A. Received in formalin labeled "Right neck level 3&4" consists of an unoriented portion of fibroadipose tissue 6.2 x 2.1 x 1.4 cm. Sixteen possible lymph nodes are identified. The largest of which 0.6 cm in greatest dimension. Cassettes are submitted as follows:

Cassettes #1-3 Four lymph nodes per cassette
Cassettes #4&5 Three lymph nodes per cassette
Cassettes #6-8 Indurated fatty tissue

- B. Received in formalin labeled "Right neck level 1" is a portion of fibrofatty tissue 4.1 x 2.3 x 1.2 cm. One grossly positive lymph node is identified which measures 1.1 cm in greatest dimension. Four other lymph nodes are identified. Portion of salivary gland is present 3.1 x 2.1 x 1.1 cm. Cassettes are submitted as follows:

Cassette #1 Grossly positive lymph node, bisected and submitted in toto in one

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail. [REDACTED]

[page 6 of 8]
(Continued)

GROSS DESCRIPTION: (Continued)

cassette
Cassette #2 Three possible lymph nodes
Cassette #3 One lymph node
Cassettes #4&5 Resection of salivary gland

- C. Received in formalin labeled "Right neck level 2" is an unoriented portion of fibrofatty tissue 4.9 x 3.6 x 4.5 cm. One grossly positive lymph node is identified 2.2 x 1.5 x 1.1 cm. No other lymph nodes are identified. Cassettes are submitted as follows:

Cassettes #1-4 Large lymph node, submitted in toto and multisectioned
Cassettes #5&6 Sections of indurated fatty tissue

- D. Received in formalin labeled "Additional right level 4 tissue" consists of a portion of gray-tan tissue 0.7 x 0.4 x 0.3 cm. Submitted in toto in one cassette.

- E. Received is a "Partial glossectomy specimen" measuring 6.1 cm from the anterior to posterior, 4.1 cm from superior to inferior and 3.6 cm from lateral to lateral. The margins are oriented as follows:

Yellow is anterior
Red is medial
Black is posterior

Ulcerated tumor is present 4.1 x 3.1 cm in diameter. The lesion is 0.5 cm from the anterior margin. 0.6 cm from the posterior resection margin, and 3mm from the medial margin. The depth of the lesion upon sectioning is 0.7 cm. Cassettes are submitted as follows:

Cassette #1 Perpendicular anterior margin
Cassette #2 Perpendicular posterior margin
Cassettes #3-9 Sections of lesion in relation to medial margin

- F. Received fresh for frozen section labeled "Dorsal tongue" are multiple portions of red-tan tissue 2.1 x 1.1 x 0.3 cm in aggregate. Submitted in toto in one cassette.
- G. Received fresh for frozen section labeled "Proximal margin right lingual nerve" is a portion of red-tan tissue 0.6 x 0.5 x 0.3 cm. Submitted in toto in one cassette.
- H. Received fresh for frozen section labeled "Right base of tongue" is a portion of red-tan tissue 1.9 x 0.4 x 0.3 cm. Submitted in toto in one cassette for frozen

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

[page 7 of 8]
(Continued)

GROSS DESCRIPTION: (Continued)
section.

- I. Received fresh for frozen section labeled "Right anterior tonsillar pillar" is a portion of red-tan tissue 0.4 x 0.4 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- J. Received in formalin labeled "Retromolar trigone" is a portion of red-tan tissue 1.2 x 0.3 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- K. Received in formalin labeled "Right floor of mouth" is a portion of red-tan tissue 1.5 x 0.4 x 0.3 cm in greatest dimension. Submitted in toto in one cassette for frozen section.
- L. Received fresh for frozen section labeled "Ventral tongue" are multiple portions of red-tan tissue 1.1 x 0.4 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- M. Received fresh for frozen section labeled "Deep margin base of tongue" is a portion of red-tan tissue 0.6 x 0.5 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- N. Received fresh for frozen section labeled "Deep margin anterior" is a portion of red-tan tissue 0.5 x 0.4 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- O. Received in formalin labeled "Deep margin-deep tongue" is a portion of red-tan tissue 0.5 x 0.4 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- P. Received fresh for frozen section labeled "Level V lymph node" is a portion of fatty tissue 2.6 x 1.5 x 0.3 cm. One minute lymph node is identified. Possible lymph nodes identified 0.2 x 0.2 x 0.1 cm. The lymph node is bisected. The touch prep is taken and submitted in toto in one cassette for frozen section. Remaining tissue is submitted in toto for permanent section.
- Q. Received in formalin labeled "Distal right hypoglossal" is a portion of red-tan tissue 0.5 x 0.3 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- R. Received in formalin labeled "Submental triangle" is a portion of fibrofatty tissue 3.1 x 1.5 x 1.1 cm. Three possible lymph nodes are identified. Largest of which measures 0.6 cm in diameter. The specimen is submitted in toto as follows:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail. [REDACTED]

[page 8 of 8]
(Continued)

GROSS DESCRIPTION: (Continued)

Cassette #1 Three lymph nodes in toto
Cassettes #2&3 Remaining tissue in toto

Sig

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED]
return the report to us by mail.

Source: NCI Genomic Data Commons file 7533ffaf-f9cf-4eac-bcd7-917a5fab8ee1 (TCGA-IQ-A61K.CC82F2BF-BEDF-46C1-BB67-5266A6E351DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).